Somatic mutation profile of tumor specimen TARGET-10-PANXGM-09A (aliquot TARGET-10-PANXGM-09A-01D) from TARGET case TARGET-10-PANXGM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,490 days).
Specimen TARGET-10-PANXGM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f755028-3e2a-498e-b415-d6ca0bf7151c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXGM-10A (Blood Derived Normal), aliquot TARGET-10-PANXGM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e05cc1f2-55c5-4f1f-85b6-afa9a849947c

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3779+1G>A p.X1260_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as rs587783483, COSV52116972, COSV52125768, COSV52132996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBL | c.1082T>A p.I361N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1206278540; called by muse, mutect2
- IL3 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | PolyPhen benign (0); catalogued as rs780057953, COSV57309631; called by muse, mutect2, varscan2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, mutect2
- MAGEE1 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 45/53 reads (85%) | catalogued as rs782646202; called by muse, mutect2, varscan2
- MSLN | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs141731036; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199722656, COSV59135308, COSV59138877; called by muse, mutect2, varscan2
- VCAN | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370476323; called by muse, mutect2, varscan2
- DCDC1 | c.4401T>A p.D1467E (on ENST00000597505 / NM_001367979.1; = p.D574E on NM_020869.3) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IQCA1 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MRAP2 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDE7B | c.481A>C p.M161L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBE3B | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ZNF518A | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- AC092070.2 | n.61G>A | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- C12orf60 | c.*59A>G | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
